Surgical pathology report (de-identified scan), TCGA case TCGA-98-A53A, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Alabama, specimen TCGA-98-A53A-01A (Primary Tumor).

[page 1 of 2]
Patient Name	MR#	Observation Date	Last Edited Date

SURGICAL PATHOLOGY CASE:

Diagnosis

- A. Lymph node, level IX-A, excision: - Negative for malignancy.
- B. Lymph node, level IX-B, excision: - Negative for malignancy.
- C. Lymph node, level VIII, excision: - Negative for malignancy.
- D. Lymph node, level VII-A, excision: - Negative for malignancy.
- E. Lymph node, level VII-B, excision: - Negative for malignancy.
- F. Lymph node, level VII-C, excision: - Negative for malignancy.
- G. Lymph node, level VII-D, excision: - Negative for malignancy.
- H. Lymph node, level VII-E, excision: - Negative for malignancy.
- I. Lymph node, level VII-F, excision: - Negative for malignancy.
- J. Lymph node, level X, excision: - Negative for malignancy.
- K. Lymph node, level II-R, excision: - Negative for malignancy.
- L. Lymph node, level IV-A, excision: - Negative for malignancy.
- M. Lymph node, level IV-B, excision: - Negative for malignancy.
- N. Lymph node, level IV-C, excision: - Negative for malignancy.
- O. Lymph node, level IV-D, excision: - Negative for malignancy.
- P. Lymph node, level IV-E, excision: - Negative for malignancy.
- Q. Lymph node, level XII, excision: - Negative for malignancy.

*ICD-0-3
Carcinoma, squamous cell, NOS 8070/3
Site: lung, @ middle lobe C34.2*

*hw
11/25/12*

R. Lung, right middle lobe, excision: - Squamous cell carcinoma, moderately differentiated. - The tumor measures 3.5 cm in maximum dimension. - Vascular invasion is present. - The pleura is uninvolved by tumor.

S. Bronchial margin, biopsy: - Negative for malignancy.

Clinical Information: The patient is a year old black male with right middle lobe mass.

Frozen Section Diagnosis

RFS1: Lung, right middle lobe, lobectomy: - Squamous cell carcinoma.
SFS1: Bronchial margin, excision: - Negative for carcinoma.

Gross Description

The specimen is received in nineteen containers, each labeled with the patients name and medical record number. The first container is labeled "level 9 lymph node - A." It consists of 1 cm in greatest dimension yellow-tan tissue, submitted in its entirety.

The second container is labeled "level 9 lymph node -B." It consists of nodal tissue measuring 0.8 cm in greatest dimension, it is placed in a single cassette in its entirety.

The third container is labeled "level 8 lymph node." It consists of nodal tissue measuring 0.7 cm in greatest dimension, submitted in its entirety.

The fourth container is labeled "level 7 lymph node - A." It consists of fragmented and black-yellow tissue measuring 1.5 cm in greatest dimension, submitted in its entirety.

[page 2 of 2]
K1- Level 2R lymph node.
L1- Level 4 lymph node - A.
M1- Level 4 lymph node - B.
N1- Level 4 lymph node - C.
O1- Level 4 lymph node - D.
P1- Level 4 lymph node - E.
Q1- Level 12 lymph node.
R1- Frozen section.
R2-R3 Stapled margin.
R4-R10 Tumor.
R11- Representative section through uninvolved lung.
S1- Bronchial margin.

Microscopic Description

A microscopic examination has been performed.

SP Synoptic Report R: Thorax Lung

SPECIMEN: Lobe(s) of lung: RML

PROCEDURE: Lobectomy

SPECIMEN INTEGRITY: Intact

SPECIMEN LATERALITY: Right

TUMOR SITE: Middle lobe

TUMOR SIZE: Greatest dimension: 3.5 cm

TUMOR FOCALITY: Unifocal

HISTOLOGIC TYPE: Squamous cell carcinoma

HISTOLOGIC GRADE: G2: Moderately differentiated

VISCERAL PLEURA INVASION: Not identified

TUMOR EXTENSION: Not identified

BRONCHIAL MARGIN: Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION: Present

PRIMARY TUMOR (pT): pT2a: Tumor > 3 cm, and < 5 cm in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion in the main bronchus; or Tumor < 5 cm in greatest dimension with any of the following: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region

REGIONAL LYMPH NODES (pN): pN0: No regional lymph node metastasis

DISTANT METASTASIS (pM): Not applicable

HL/AA Discrepancy		✓
History of Malignancy History		
Primary/Synchronous Primary Malignancy		

11/8/12

Source: NCI Genomic Data Commons file d6632e66-dc60-4653-9e4f-14da7c20d45e (TCGA-98-A53A.3E2F6DF6-5C59-4B1B-887E-B080532548A1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).